RC case RC-B6SF — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5ba8feef-f81d-411c-a71c-4993661e63a5

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Dead; Days to death: 352 days; Year of death: 2016; Cause of death: Cancer Related.

Diagnoses (5)
1. Peripheral T-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Lymph nodes of head, face and neck; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 61.6 years (22,500 days); Year of diagnosis: 2015; Method of diagnosis: Core Biopsy; Prior malignancy: no; Synchronous malignancy: No; International Prognostic Index (IPI): Low Risk.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab + Pentostatin; Initial disease status: Initial Diagnosis; Days to treatment start: 51 days; Days to treatment end: 144 days; Number of cycles: 3; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Progressive Disease; Regimen or line of therapy: EPOCH; Days to treatment start: 122 days; Days to treatment end: 215 days; Number of cycles: 3; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Dexamethasone + Gemcitabine; Initial disease status: Progressive Disease; Regimen or line of therapy: GDP; Days to treatment start: 251 days; Days to treatment end: 251 days; Number of cycles: 1; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Dexamethasone + Doxorubicin + Vincristine; Initial disease status: Progressive Disease; Regimen or line of therapy: HyperCVAD; Days to treatment start: 274 days; Days to treatment end: 295 days; Number of cycles: 2; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Methotrexate; Initial disease status: Progressive Disease; Days to treatment start: 329 days; Days to treatment end: 344 days; Number of cycles: 2; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Recorded as not given: Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous.
2. Progression (histology not recorded by GDC). Age at diagnosis: 61.9 years (22,617 days); Days to diagnosis: 117 days.
3. Progression (histology not recorded by GDC). Age at diagnosis: 62.3 years (22,750 days); Days to diagnosis: 250 days.
4. Progression (histology not recorded by GDC). Age at diagnosis: 62.4 years (22,774 days); Days to diagnosis: 274 days.
5. Progression (histology not recorded by GDC). Age at diagnosis: 62.5 years (22,828 days); Days to diagnosis: 328 days.

Follow-up (6 entries)
- Day 117 (progression): Progression or recurrence: Yes; Days to progression: 117 days.
- Days to follow up: 211 days; Disease response: Partial Response.
- Day 250 (progression): Progression or recurrence: Yes; Days to progression: 250 days.
- Day 274 (progression): Progression or recurrence: Yes; Days to progression: 274 days.
- Day 328 (progression): Progression or recurrence: Yes; Days to progression: 328 days.
- Follow-up contacts recording only the day: day 119, day 352.

Molecular and laboratory tests
- Lactate Dehydrogenase 1816 U/L [Blood test normal range upper: 618].

Biospecimens (2 samples)
- Sample RC-B6SF-NB1-A: Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample RC-B6SF-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
